Surgical pathology report (de-identified scan), TCGA case TCGA-J2-A4AD, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J2-A4AD-01A (Primary Tumor).

[page 1 of 6]
COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Final

Results

Final

Source of Specimen

- A. ST 7 #1 FS-
- B. ST 7 #2 FS-
- C. ST 7 #3 FS-
- D. 4L #1 FS-
- E. 4L #2 FS-
- F. 4L #3 FS-
- G. 4R #1 FS-
- H. 4R #2 FS-
- I. 4R #3 FS-
- J. 4R #4 FS-
- K. LEFT UPPER LOBE LUNG WEDGE FS-
- L. LEFT UPPER LOBE LUNG WEDGE
- M. STATION 5 NODE-
- N. HILAR NODE #1-
- O. HILAR NODE #2-
- P. HILAR NODE #3-
- Q. INTERLOBAR NODE-
- R. LEFT UPPER LOBE COMPLETION LOBECTOMY-

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: lung, upper lobe C34.1

hw
9/24/12

FINAL DIAGNOSIS:

- A. ST 7 #1 FS-
LYMPH NODE, NO TUMOR SEEN.
- B. ST 7 #2 FS-
LYMPH NODE, NO TUMOR SEEN.
- C. ST 7 #3 FS-
LYMPH NODE, NO TUMOR SEEN.
- D. 4L #1 FS-
LYMPH NODE, NO TUMOR SEEN.

Prep

[page 2 of 6]
E. 4L #2 FS-
LYMPH NODE, NO TUMOR SEEN.
F. 4L #3 FS-
LYMPH NODE, NO TUMOR SEEN.
G. 4R #1 FS-
LYMPH NODE, NO TUMOR SEEN.
H. 4R #2 FS-
LYMPH NODE, NO TUMOR SEEN.
I. 4R #3 FS-
LYMPH NODE, NO TUMOR SEEN.
J. 4R #4 FS-
LYMPH NODE, NO TUMOR SEEN.
K. LEFT UPPER LOBE LUNG WEDGE FS-
SEE PART L.
L. LEFT UPPER LOBE LUNG WEDGE NFS-
INVASIVE CARCINOMA, LIMITED TO LUNG.

HISTOLOGIC TYPE: ADENOCARCINOMA.

HISTOLOGIC GRADE: 1/4.

TUMOR FOCALITY: UNIFOCAI.

TUMOR SIZE: 1.8 CM.

TUMOR SITE: LEFT UPPER LOBE.

VISCERAL PLEURA INVASION: NOT SEEN.

NO SIGNIFICANT OBSTRUCTIVE PNEUMONITIS OR ATELECTASIS SEEN.

LYMPHATIC (SMALL VESSEL) INVASION: NOT SEEN.

LARGE VESSEL INVASION: NOT SEEN.

LYMPH NODES INCLUDED IN ALL PARTS: NUMBER INVOLVED : 0
NUMBER EXAMINED: 14

TNM STAGE: pT1a, pN0, pMX.

SPECIMEN TYPE: WEDGE RESECTION, WITH COMPLETION LOBECTOMY.

SPECIMEN SIZE: 9 x 2.5 x 2.0 CM.

NO TUMOR SEEN AT RESECTION MARGINS.

M. STATION 5 NODE-
LYMPH NODE, NO TUMOR SEEN..

N. HILAR NODE #1-

FRAGMENT OF FIBROVASCULAR TISSUE, NEGATIVE FOR MALIGNANCY.

Prep

[page 3 of 6]
O. HILAR NODE #2-
LYMPH NODE, NO TUMOR SEEN.
P. HILAR NODE #3-
LYMPH NODE, NO TUMOR SEEN.
Q. INTERLOBAR NODE-
LYMPH NODE, NO TUMOR SEEN.
R. LEFT UPPER LOBE COMPLETION LOBECTOMY-
LUNG WITHOUT SIGNIFICANT ABNORMALITY.
NO CARCINOMA SEEN.

Signature

Signed Others

Frozen Section

A. 10 SPECIMENS:: ST7 #1, ST7#2, ST7 #3, 4L #1, 4L #2, 4L #3,
4R #1, 4R #2, 4R #3, 4R #4.
NO TUMOR SEEN.

LEFT UPPER LOBE WEDGE: ADENOCARCINOMA.

Case Clinical Information

LEFT UPPER LOBE LUNG

Gross Description

- A. Received in formalin labeled with the patient's name and "ST 7 #1 FS" are two dark brown tissue fragments measuring 0.5 x 0.2 cm. Filtered, wrapped and submitted in A1.
- B. Received in formalin labeled with the patient's name and "ST 7 #2 FS" are two gray-tan tissue fragments; the larger fragment measures 0.5 cm and the smaller fragment measures 0.2 cm. Wrapped and submitted in B1.
- C. Received in formalin labeled with the patient's name and "ST 7 #3 FS" is a gray-tan frozen section tissue fragment measuring 0.4 x 0.3 cm. Filtered, wrapped and submitted in C1.
- D. Received in formalin labeled with the patient's name and "4L #1 FS" is a gray-tan frozen section tissue fragment measuring 0.4 cm. Wrapped and submitted in D1.
- E. Received in formalin labeled with the patient's name and "4L

[page 4 of 6]
#2 FS" are three gray-brown tissue fragments measuring 0.5 x 0.2 cm. Wrapped and submitted in E1.

F. Received in formalin labeled with the patient's name and "4L #3 FS" are two gray-brown tissue fragments measuring 0.4 x 0.4 cm. Wrapped and submitted in F1.

G. Received in formalin labeled with the patient's name and "4R #1 FS" are two yellow-brown tissue fragments. The larger fragment measures 1 x 0.5 cm and the smaller fragment measures 0.5 x 0.4 cm. Wrapped and submitted in G1.

H. Received in formalin labeled with the patient's name and "4R #2 FS" are three yellow-brown tissue fragments. The largest fragment measures 0.5 cm and the smallest fragment measures 0.3 cm. Wrapped and submitted in H1.

I. Received in formalin labeled with the patient's name and "4R #3 FS" are two yellow-tan fibroadipose tissue fragments measuring 0.5 cm. Wrapped and submitted in I1.

J. Received in formalin labeled with the patient's name and "4R #4 FS" are four yellow-tan fibroadipose tissue fragments. The largest fragment measures 0.9 x 0.5 cm and the smallest fragment measures 0.5 x 0.4 cm. Wrapped and submitted in J1.

K. Received in formalin labeled with the patient's name and "left upper lobe lung wedge FS" is a gray-tan frozen section tissue fragment measuring 2.2 x 1.5 cm. Wrapped and submitted in K1.

L. Received in formalin labeled with the patient's name and "left upper lobe lung wedge NFS" is a gray-brown wedge of lung weighing 26 grams and measures 9 x 2.5 x 2.0 cm. The specimen has a staple line at one of the edges which are removed and inked in black. The specimen has been previously sectioned from where a frozen section has been taken showing a gray dark brown friable firm area and measures 2 x 1.7 cm. The pleura lesion is inked in blue. The remainder of the parenchyma is serially sectioned showing a gray dark brown parenchyma. Represented as follows: the firm area adjacent area from where the frozen section was taken entirely submitted L1-L7; lung parenchyma through the black inked resection margin L8-L10.

M. Received in formalin labeled with the patient's name and "station 5 lymph node" is a dark brown tissue fragment measuring 0.9 x 0.5 cm. Entirely submitted in M1.

N. Received in formalin labeled with the patient's name and "hilar node #1" is a gray-brown tissue fragment measuring 0.5 cm. Wrapped and submitted in N1.

O. Received in formalin labeled with the patient's name and "hilar node #2" are two yellow-tan fibroadipose tissue fragments. The larger fragment measures 0.9 cm and the smaller fragment measures 0.4 cm. Wrapped and entirely submitted in O1.

P. Received in formalin labeled with the patient's name and "hilar node #3" revealed tan fibroadipose tissue fragments. The

[page 5 of 6]
larger fragment measures 0.5 cm and the smaller fragment measures 0.2 cm. Wrapped and submitted in P1.

Q. Received in formalin labeled with the patient's name and "interlobar node" are three dark brown fibroadipose tissue fragments. The largest fragment measures 0.8 x 0.5 cm and the smallest fragment measures 0.4 x 0.4 cm. Wrapped and submitted in Q1.

R. Received in formalin labeled with the patient's name and "left upper lobe, completion lobectomy" is a left upper lobe lung weighing 200 grams measuring 17 x 8 x 4.5 cm. The pleura is a gray dark brown with moderate anthracotic streaking and has a staple line at one of the edges which are removed and inked in black. The specimen is serially sectioned showing a gray dark brown, spongy and congested parenchyma. No tumor grossly identified. The specimen is represented as follows: parenchymal resection margin = R1; lung parenchyma = R2-R4; parenchyma through the staple inked resection margin = R5-R7.

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK
H&E X1
- C. AA ROUTINE H&E X1 BLOCK
H&E X1
- D. AA ROUTINE H&E X1 BLOCK
H&E X1
- E. AA ROUTINE H&E X1 BLOCK
H&E X1
- F. AA ROUTINE H&E X1 BLOCK
H&E X1
- G. AA ROUTINE H&E X1 BLOCK
H&E X1
- H. AA ROUTINE H&E X1 BLOCK
H&E X1
- I. AA ROUTINE H&E X1 BLOCK
H&E X1
- J. AA ROUTINE H&E X1 BLOCK
H&E X1
- K. AA ROUTINE H&E X1 BLOCK
H&E X1
- L. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- M. AA ROUTINE H&E X1 BLOCK.2

[page 6 of 6]
H&E X1
L. AA ROUTINE H&E X1 BLOCK.3
H&E X1
L. AA ROUTINE H&E X1 BLOCK.4
H&E X1
L. AA ROUTINE H&E X1 BLOCK.5
H&E X1
L. AA ROUTINE H&E X1 BLOCK.6
H&E X1
L. AA ROUTINE H&E X1 BLOCK.7
H&E X1
L. AA ROUTINE H&E X1 BLOCK.8
H&E X1
L. AA ROUTINE H&E X1 BLOCK.9
H&E X1
L. AA ROUTINE H&E X1 BLOCK.10
H&E X1
M. AA ROUTINE H&E X1 BLOCK
H&E X1
N. AA ROUTINE H&E X1 BLOCK
H&E X1
O. AA ROUTINE H&E X1 BLOCK
H&E X1
P. AA ROUTINE H&E X1 BLOCK
H&E X1
Q. AA ROUTINE H&E X1 BLOCK
H&E X1
R. AA ROUTINE H&E X1 BLOCK.1
H&E X1
R. AA ROUTINE H&E X1 BLOCK.2
H&E X1
R. AA ROUTINE H&E X1 BLOCK.3
H&E X1
R. AA ROUTINE H&E X1 BLOCK.4
H&E X1
R. AA ROUTINE H&E X1 BLOCK.5
H&E X1
R. AA ROUTINE H&E X1 BLOCK.6
H&E X1
R. AA ROUTINE H&E X1 BLOCK.7
H&E X1

Prepare:

Diagnostic Discrepancy		
Local Malignancy History		
Local/Synchronous Primary Entry Noted		

9/11/12

Source: NCI Genomic Data Commons file 0407e865-5471-4542-8eb8-658fda0abaf7 (TCGA-J2-A4AD.C7D2CA13-F82C-4B95-9161-E9D8C8D958E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).